Somatic mutation profile of cancer-model specimen HCM-BROD-0677-C43-85M (Adherent Cell Line, passage 3; aliquot HCM-BROD-0677-C43-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0677-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 55.1 years (20,120 days).
Specimen HCM-BROD-0677-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce6e5059-8978-4cc0-a948-444081989147.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0677-C43-12A (Saliva), aliquot HCM-BROD-0677-C43-12A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7c5b85e-6cb4-45d6-8092-5abb47b2841f

The open-access MAF lists 400 somatic variants for this specimen: 261 protein-altering or splice-affecting, 122 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 122, Nonsense Mutation 22, Intron 8, 3'UTR 4, RNA 2, Splice Region 2, 5'Flank 2, In Frame Del 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.7138C>T p.Q2380* | Nonsense Mutation (SNP) | VAF 325/596 reads (55%) | catalogued as rs1057520565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/323 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 581/582 reads (100%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14662G>A p.D4888N | Missense Mutation (SNP) | VAF 134/454 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397241273; called by muse, varscan2
- ABCB1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 168/555 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55945144; called by muse, mutect2, varscan2
- ABO | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 696/696 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs375174031; called by muse, mutect2, varscan2
- ADAM20 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 247/355 reads (70%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56457247; called by muse, mutect2, varscan2
- ADAMDEC1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 109/193 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs868610362, COSV56474181; called by muse, mutect2, varscan2
- ADAMTSL1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777583332, COSV52813087; called by muse, mutect2, varscan2
- ADGRF3 | c.2000C>T p.P667L (on ENST00000311519 / NM_001145168.1; = p.P468L on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/493 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs143113161; called by muse, mutect2, varscan2
- ADGRV1 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 211/291 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755802203; called by muse, mutect2, varscan2
- AHNAK2 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 103/1191 reads (9%) | catalogued as COSV100318059; called by muse, mutect2
- ALDH3A1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 999/1000 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749325435; called by muse, mutect2, varscan2
- ANGPTL5 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 160/161 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100527717; called by muse, mutect2, varscan2
- ATXN1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 170/474 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763415634, COSV55214325; called by muse, varscan2
- ATXN7 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 378/378 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.109); catalogued as rs750956545; called by muse, mutect2, varscan2
- BHMT | c.968C>G p.P323R | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1054252814; called by muse, mutect2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 191/324 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BRINP2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 260/569 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs777721842; called by muse, mutect2, varscan2
- C9 | c.143G>A p.W48* | Nonsense Mutation (SNP) | VAF 229/330 reads (69%) | catalogued as rs1041910675; called by muse, mutect2, varscan2
- CAMKK1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 452/453 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV50119687, COSV50125741; called by muse, mutect2, varscan2
- CAPZA3 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 309/311 reads (99%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56851738; called by muse, mutect2, varscan2
- CATIP | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 109/392 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs1162566137; called by muse, mutect2, varscan2
- CCDC77 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1467629558; called by muse, mutect2, varscan2
- CDH10 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV52588750; called by muse, mutect2, varscan2
- CDH4 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 122/1594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64648404; called by muse, mutect2
- CDH9 | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 204/275 reads (74%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs1372440494, COSV50414079; called by muse, mutect2, varscan2
- CDK9 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 482/483 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774630568; called by muse, mutect2, varscan2
- CEP131 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 329/329 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs753942447; called by muse, mutect2, varscan2
- CFAP46 | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 345/386 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV63955509; called by muse, mutect2, varscan2
- CFAP54 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 123/169 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1345081413, COSV73047095; called by muse, mutect2, varscan2
- CLEC4E | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs768306307, COSV55226802; called by muse, mutect2, varscan2
- COL6A3 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 139/425 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV55083096; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- CRISPLD2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs200281033, COSV52284063, COSV99295670; called by muse, mutect2, varscan2
- CTAGE9 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 256/292 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757749284, COSV58419065; called by muse, varscan2
- CTC1 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 579/580 reads (100%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs369917627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4B1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 225/464 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1442243201, COSV54725495; called by muse, mutect2, varscan2
- DGCR2 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 615/615 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54221247; called by muse, mutect2, varscan2
- DKK2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770400633, COSV53394433; called by muse, mutect2, varscan2
- DMBT1 | c.6319C>T p.R2107C (on ENST00000338354 / NM_001377530.1; = p.R1350C on NM_004406.3) | Missense Mutation (SNP) | VAF 192/203 reads (95%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs747972203, COSV57544508; called by muse, mutect2, varscan2
- DNAH9 | c.4519G>C p.A1507P | Missense Mutation (SNP) | VAF 458/459 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV52374884; called by muse, mutect2, varscan2
- E2F3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1225039532; called by muse, mutect2, varscan2
- EIF3D | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1408127445; called by muse, mutect2, varscan2
- ESAM | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 309/309 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV54034108; called by muse, mutect2, varscan2
- EYS | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as CM157893, COSV60997369, COSV60998112; called by muse, mutect2, varscan2
- F9 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs779281053, CM1313085, COSV99028975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHL5 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58735968; called by muse, mutect2, varscan2
- FMN1 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 207/573 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.382); catalogued as rs930794999; called by muse, mutect2, varscan2
- FMNL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 150/240 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs777087549, COSV56491973; called by muse, mutect2, varscan2
- FZD6 | c.1758G>T p.L586F | Missense Mutation (SNP) | VAF 28/610 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100708440; called by muse, mutect2
- GALNT18 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1035041054, COSV57151646; called by muse, mutect2, varscan2
- GFRA1 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 201/463 reads (43%) | catalogued as rs764537841, COSV62607138; called by muse, mutect2, varscan2
- GNG14 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as rs1326481762; called by muse, mutect2
- GOLGA6L2 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 363/1024 reads (35%) | SIFT deleterious, low confidence (0.01); catalogued as rs1295580440; called by mutect2, varscan2
- GPHN | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 245/372 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868177928; called by muse, mutect2, varscan2
- GRXCR1 | c.797C>G p.T266R | Missense Mutation (SNP) | VAF 98/565 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101295760; called by muse, mutect2, varscan2
- HEATR5B | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs1408611803; called by muse, mutect2, varscan2
- KCNH8 | c.3056C>T p.T1019M | Missense Mutation (SNP) | VAF 374/374 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs200231499, COSV60457021; called by muse, mutect2, varscan2
- KCNU1 | c.2038T>G p.S680A | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV67760216; called by muse, mutect2, varscan2
- KIF16B | c.3853A>G p.I1285V | Missense Mutation (SNP) | VAF 73/650 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs958637957; called by muse, mutect2, varscan2
- KIF4B | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 158/236 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV70530360; called by muse, mutect2, varscan2
- KLHDC7A | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 284/696 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252925653; called by muse, mutect2, varscan2
- LAMA3 | c.9854C>T p.P3285L (on ENST00000313654 / NM_198129.4; = p.P1676L on NM_000227.6) | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568385960; called by muse, mutect2, varscan2
- LPIN1 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen probably damaging (0.971); catalogued as rs993645656; called by muse, mutect2, varscan2
- LRFN5 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 180/449 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV53253279; called by muse, mutect2, varscan2
- LRRC72 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 119/384 reads (31%) | catalogued as rs780558703, COSV69130958; called by muse, mutect2, varscan2
- MAP7D2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV65525611; called by muse, mutect2, varscan2
- MARF1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 126/488 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs755224148, COSV60020455; called by muse, mutect2, varscan2
- MAVS | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 281/762 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs749064057; called by muse, mutect2, varscan2
- MCC | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 275/409 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1361384286; called by muse, mutect2, varscan2
- MED12L | c.2422A>T p.N808Y | Missense Mutation (SNP) | VAF 105/405 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs749502287; called by muse, mutect2, varscan2
- MGAM | c.3986C>T p.P1329L | Missense Mutation (SNP) | VAF 143/514 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1281147281, COSV72073920; called by muse, mutect2, varscan2
- MMRN1 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 314/314 reads (100%) | catalogued as COSV104392869; called by mutect2, varscan2
- MRPS18A | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs755849170; called by muse, mutect2, varscan2
- MTUS2 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 429/430 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs747494603, COSV70916004; called by muse, mutect2, varscan2
- MUC16 | c.27589A>G p.T9197A | Missense Mutation (SNP) | VAF 29/552 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs867272580, COSV67454097; called by muse, mutect2
- MUC16 | c.7888C>T p.P2630S | Missense Mutation (SNP) | VAF 18/349 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67476439; called by muse, mutect2
- MUC17 | c.12311C>T p.S4104F | Missense Mutation (SNP) | VAF 576/942 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs868211635, COSV60292092; called by muse, mutect2, varscan2
- NFYC | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 301/528 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs932186866, COSV58125995; called by muse, mutect2, varscan2
- NIBAN3 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 375/397 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs1164314238; called by muse, mutect2, varscan2
- NLRP10 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 530/532 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.387); catalogued as rs866417661, COSV60781132; called by muse, mutect2, varscan2
- NMBR | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57800668; called by muse, mutect2, varscan2
- NRIP3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.52); catalogued as rs372652266, COSV58468772; called by muse, mutect2, varscan2
- NUDT3 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101657149; called by muse, mutect2, varscan2
- OR1R1P | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 376/377 reads (100%) | catalogued as rs1215333314; called by muse, mutect2, varscan2
- OR2M3 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 183/324 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV71758873; called by muse, mutect2, varscan2
- OR4K14 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 327/475 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59292718; called by muse, mutect2, varscan2
- P2RX5 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 428/428 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV99835797; called by muse, mutect2, varscan2
- PCDHB14 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as rs782632036, COSV53391335, COSV53391551; called by muse, mutect2, varscan2
- PCDHB5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 343/466 reads (74%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV50647173; called by muse, mutect2, varscan2
- PCDHGA2 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 368/527 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53938726; called by muse, mutect2, varscan2
- PCLO | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 177/590 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV61665281; called by muse, mutect2, varscan2
- PDE8A | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 329/602 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100052362; called by muse, mutect2, varscan2
- PHF23 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV50034915; called by muse, mutect2
- PPM1K | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 69/428 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774946986; called by muse, mutect2, varscan2
- SELE | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 148/356 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.131); catalogued as rs765834275; called by muse, mutect2, varscan2
- SERPINA10 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 105/494 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56228075; called by muse, mutect2, varscan2
- SI | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1480391241, COSV52268016, COSV52270226, COSV52276610; called by muse, mutect2, varscan2
- SLC16A3 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 183/868 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs377324766; called by muse, mutect2, varscan2
- SLC38A1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs1012157182; called by muse, mutect2, varscan2
- SLC38A4 | c.886G>C p.G296R | Missense Mutation (SNP) | VAF 140/754 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56968417; called by muse, mutect2, varscan2
- SLC52A2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 408/572 reads (71%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs781928955, COSV57352133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A7 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 231/350 reads (66%) | SIFT tolerated (0.53); PolyPhen benign (0.27); catalogued as rs774267102; called by muse, mutect2, varscan2
- SLC8A1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 237/351 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60489961; called by muse, mutect2, varscan2
- SLCO5A1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 419/535 reads (78%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV52653520; called by muse, mutect2, varscan2
- SLIT3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 200/257 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100265313, COSV60626351; called by muse, mutect2, varscan2
- SRGN | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 185/186 reads (99%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs573683161; called by muse, mutect2, varscan2
- STARD8 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 164/620 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99367413; called by mutect2, varscan2
- SYNE3 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 589/789 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62081291; called by muse, mutect2, varscan2
- SYT3 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 38/822 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58896410; called by muse, mutect2
- TBL2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 276/888 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59786083; called by muse, varscan2
- TCIRG1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs772440359, COSV55835017; ClinVar: uncertain significance; called by muse, varscan2
- TMEM132D | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756515507; called by muse, mutect2, varscan2
- TMEM176B | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 209/737 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100423654, COSV58440211; called by muse, mutect2, varscan2
- TPR | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 325/690 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs747963329, COSV66603352; called by muse, mutect2, varscan2
- TRBV28 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 170/546 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1436668301; called by muse, mutect2, varscan2
- TTN | c.83755G>A p.D27919N (on ENST00000591111; = p.D20495N on NM_003319.4) | Missense Mutation (SNP) | VAF 289/448 reads (65%) | PolyPhen probably damaging (0.951); catalogued as COSV60358481; called by muse, mutect2, varscan2
- VEPH1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 160/274 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1242970859, COSV62882688; called by muse, mutect2, varscan2
- WDR33 | c.3016C>T p.H1006Y | Missense Mutation (SNP) | VAF 322/508 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.14); catalogued as rs771639906; called by muse, mutect2, varscan2
- XG | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 457/459 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66986114; called by muse, mutect2, varscan2
- ZFP37 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 30/529 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as rs1010350397; called by muse, mutect2
- ZNF532 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs893165935, COSV60173376; called by muse, mutect2, varscan2
- ZNF544 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 288/310 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV54135136; called by muse, mutect2, varscan2
- ZNF679 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as COSV55380869, COSV55381251; called by muse, mutect2, varscan2
- ZP1 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 503/503 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs759093238; called by muse, mutect2, varscan2
- AACS | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 120/496 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ABCA7 | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 441/467 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ABCA8 | c.4650T>G p.V1550= | Splice Region (SNP) | VAF 68/342 reads (20%) | called by muse, mutect2, varscan2
- ABCB7 | c.592G>A p.V198I (on ENST00000373394 / NM_001271696.3; = p.V199I on NM_004299.6) | Missense Mutation (SNP) | VAF 144/225 reads (64%) | SIFT tolerated (0.87); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCC11 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 252/411 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ACO1 | c.743T>A p.M248K | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM23 | c.1361A>C p.E454A | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- ADAMTS2 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 141/592 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ALPG | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 163/550 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP5 | c.4241G>A p.W1414* (on ENST00000345122 / NM_001030055.2; = p.W1413* on NM_001173.3) | Nonsense Mutation (SNP) | VAF 50/551 reads (9%) | called by muse, mutect2
- ARSI | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 532/723 reads (74%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATM | c.5836C>A p.Q1946K | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATXN2L | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 137/263 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ1B | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 133/439 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- BPIFB6 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 215/595 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- BRD1 | c.2652C>A p.H884Q (on ENST00000216267 / NM_001349940.1; = p.H1015Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 105/582 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- C12orf4 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2
- C1QTNF6 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 36/902 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- C20orf194 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- C6orf141 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 129/465 reads (28%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf89 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CALML6 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 214/579 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATIP | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 107/388 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CATSPER2 | c.798C>G p.Y266* | Nonsense Mutation (SNP) | VAF 72/420 reads (17%) | called by muse, mutect2, varscan2
- CCDC149 | c.1449A>C p.E483D (on ENST00000635206 / NM_001330643.2; = p.E472D on NM_173463.5) | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); called by muse, mutect2
- CDC14A | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 139/150 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CDH4 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 107/671 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CECR2 | c.3131C>T p.P1044L (on ENST00000342247 / NM_001290047.2; = p.P860L on NM_001290046.1) | Missense Mutation (SNP) | VAF 713/715 reads (100%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFAP43 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHST15 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 205/231 reads (89%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTCL1 | c.2685A>C p.R895S | Missense Mutation (SNP) | VAF 24/772 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); called by muse, mutect2
- CNTLN | c.1498A>G p.S500G | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2
- CNTNAP3 | c.2891C>T p.T964I | Missense Mutation (SNP) | VAF 371/555 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- COL20A1 | c.3421G>A p.G1141R | Missense Mutation (SNP) | VAF 591/1131 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKK4 | c.404A>C p.Q135P | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC30 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 630/977 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- DOCK2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DPP9 | c.2270C>T p.T757I (on ENST00000598800; = p.T786I on NM_139159.5) | Missense Mutation (SNP) | VAF 373/393 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DSPP | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 25/408 reads (6%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); called by muse, mutect2
- DZIP3 | c.3257C>A p.P1086H | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EBF3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 293/315 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ECT2L | c.2495C>A p.T832N | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- EIF3D | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ENPP2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- EPHB3 | c.2175C>T p.L725= | Splice Region (SNP) | VAF 248/368 reads (67%) | called by muse, mutect2, varscan2
- EPS15L1 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERN2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 209/740 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FAM117B | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 30/754 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- FBN2 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 111/513 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FREM2 | c.2171A>T p.K724M | Missense Mutation (SNP) | VAF 22/455 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- GLG1 | c.3377C>T p.A1126V | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GPR174 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 15/479 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIA1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 74/555 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GRIN3B | c.2340C>G p.N780K | Missense Mutation (SNP) | VAF 120/442 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GTDC1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 169/288 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- HECW1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 38/1488 reads (3%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); called by muse, mutect2
- IGKV1-16 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- IGLV8-61 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 294/294 reads (100%) | called by muse, mutect2, varscan2
- IL17C | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 235/440 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- IRX2 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 148/874 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ITPKC | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 20/476 reads (4%) | called by muse, mutect2
- KBTBD12 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 288/407 reads (71%) | SIFT tolerated (0.24); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- KIF26A | c.1961G>A p.C654Y | Missense Mutation (SNP) | VAF 141/1600 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- KIF27 | c.3130G>A p.G1044S | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, varscan2
- KMT2A | c.1532_1534delinsTT p.P511Lfs*56 | Frame Shift Del (DEL) | VAF 208/490 reads (42%) | called by pindel, varscan2*
- LILRA6 | c.576G>A p.W192* | Nonsense Mutation (SNP) | VAF 568/570 reads (100%) | called by muse, mutect2, varscan2
- LRP2 | c.8768G>A p.W2923* | Nonsense Mutation (SNP) | VAF 104/350 reads (30%) | called by muse, mutect2, varscan2
- MAP2K4 | c.563T>A p.F188Y | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MARCOL | c.5G>T p.R2M | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT tolerated, low confidence (0.05); called by muse, mutect2, varscan2
- MBD5 | c.552A>T p.Q184H | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2
- MCPH1 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 123/465 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCTP1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 266/984 reads (27%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.04); called by muse, varscan2
- MPL | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 296/654 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO19 | c.1960G>T p.A654S (on ENST00000614623 / NM_001163735.1; = p.A454S on NM_025109.5) | Missense Mutation (SNP) | VAF 523/523 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NAP1L3 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 58/417 reads (14%) | called by muse, mutect2, varscan2
- NBEAL1 | c.5954C>T p.P1985L | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NCAPG2 | c.2605T>C p.Y869H | Missense Mutation (SNP) | VAF 71/477 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.18772C>T p.P6258S | Missense Mutation (SNP) | VAF 336/747 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OPHN1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OR10T2 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 205/428 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- OR11A1 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 54/845 reads (6%) | called by muse, mutect2
- OR12D2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 204/632 reads (32%) | called by muse, mutect2, varscan2
- OSTC | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OTX1 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 475/723 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- P2RX2 | c.383G>A p.S128N (on ENST00000343948 / NM_170683.4; = p.S104N on NM_016318.4) | Missense Mutation (SNP) | VAF 22/736 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); called by muse, mutect2
- PAPPA2 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PCSK6 | c.1425C>G p.F475L | Missense Mutation (SNP) | VAF 86/497 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PELP1 | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 279/341 reads (82%) | called by muse, mutect2, varscan2
- PHEX | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT tolerated (0.8); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PNPLA5 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 523/523 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- POLG | c.2385C>G p.N795K | Missense Mutation (SNP) | VAF 294/508 reads (58%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR3E | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 166/268 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- POU4F1 | c.1112A>G p.E371G | Missense Mutation (SNP) | VAF 17/544 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRAMEF1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 298/563 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRAMEF10 | c.1148A>G p.N383S | Missense Mutation (SNP) | VAF 30/622 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRR16 | c.658T>C p.C220R (on ENST00000407149 / NM_001300783.2; = p.C197R on NM_016644.2) | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PWWP2B | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.288); called by muse, mutect2
- PXDN | c.4376C>T p.P1459L | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- RBM28 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 340/583 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RGL1 | c.1168G>A p.D390N (on ENST00000360851 / NM_001297672.2; = p.D425N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 170/368 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RND1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- RNF180 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RNF38 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 389/390 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- RYR2 | c.5224G>A p.E1742K | Missense Mutation (SNP) | VAF 243/553 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A7 | c.329T>G p.I110R | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A1 | c.1300_1317del p.W434_F439del | In Frame Del (DEL) | VAF 194/625 reads (31%) | called by mutect2, pindel, varscan2
- SLK | c.1630A>C p.N544H | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2
- SPATA31A1 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 125/952 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPATA31D1 | c.2113A>T p.R705* | Nonsense Mutation (SNP) | VAF 188/743 reads (25%) | called by muse, mutect2, varscan2
- SPEF2 | c.5189G>A p.G1730E | Missense Mutation (SNP) | VAF 269/387 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SUGP2 | c.2673G>T p.M891I | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- TBC1D3F | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 356/561 reads (63%) | called by muse, mutect2, varscan2
- TBL2 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 292/941 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- TGM6 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 246/796 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TICAM1 | c.1186A>T p.N396Y | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TMEM132A | c.135C>G p.Y45* | Nonsense Mutation (SNP) | VAF 391/391 reads (100%) | called by muse, mutect2, varscan2
- TMEM266 | c.1048T>C p.C350R | Missense Mutation (SNP) | VAF 181/492 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TNRC6C | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 376/376 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNXB | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TPR | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by mutect2, varscan2
- TRIM51 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 213/237 reads (90%) | called by muse, mutect2, varscan2
- TSPAN8 | c.679T>C p.S227P | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UBLCP1 | c.241A>C p.S81R | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.204); called by muse, mutect2
- UNC80 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VAC14 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 178/309 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.9050T>G p.I3017S | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- VPS13D | c.10286C>T p.P3429L | Missense Mutation (SNP) | VAF 238/421 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- WIPF2 | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 371/371 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF284 | c.1395G>T p.R465S | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF311 | c.1784G>A p.G595D | Missense Mutation (SNP) | VAF 188/651 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF311 | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 190/651 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF512 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 108/159 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF518B | c.3168A>T p.Q1056H | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF716 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 141/238 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF728 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 176/184 reads (96%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ABCA4 | c.6015C>G p.T2005= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- ABCB11 | c.3666G>A p.G1222= | Silent (SNP) | VAF 115/411 reads (28%) | catalogued as rs1402360352; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1311C>T p.G437= | Silent (SNP) | VAF 178/245 reads (73%) | catalogued as rs779921590; called by muse, mutect2, varscan2
- ADAMTS2 | c.441C>G p.R147= | Silent (SNP) | VAF 34/1180 reads (3%) | called by muse, mutect2
- ADGRB3 | c.2619C>T p.S873= | Silent (SNP) | VAF 146/146 reads (100%) | called by muse, mutect2, varscan2
- ADGRF5 | c.1320G>A p.S440= | Silent (SNP) | VAF 257/422 reads (61%) | catalogued as rs774615419, COSV51933142; called by muse, mutect2, varscan2
- AKAP6 | c.4779C>T p.S1593= | Silent (SNP) | VAF 184/620 reads (30%) | called by muse, mutect2, varscan2
- ALPI | c.1101G>A p.E367= | Silent (SNP) | VAF 230/357 reads (64%) | called by muse, mutect2, varscan2
- ALX4 | c.129C>T p.F43= | Silent (SNP) | VAF 534/535 reads (100%) | catalogued as COSV61326336; called by muse, mutect2, varscan2
- AMPD1 | c.1575C>T p.N525= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- ARHGAP25 | c.342C>T p.I114= (on ENST00000409202 / NM_001007231.3; = p.I107= on NM_014882.3) | Silent (SNP) | VAF 172/255 reads (67%) | catalogued as COSV54907340; called by muse, mutect2, varscan2
- ARHGAP6 | c.1654C>T p.L552= | Silent (SNP) | VAF 263/263 reads (100%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.1101G>T p.L367= | Silent (SNP) | VAF 79/418 reads (19%) | catalogued as COSV55251075; called by muse, mutect2, varscan2
- ATCAY | c.51G>A p.E17= | Silent (SNP) | VAF 83/367 reads (23%) | catalogued as rs1377359395, COSV56653938; called by muse, mutect2, varscan2
- B4GALNT4 | c.162G>A p.K54= | Silent (SNP) | VAF 263/263 reads (100%) | called by muse, mutect2, varscan2
- BMP5 | c.159G>A p.R53= | Silent (SNP) | VAF 94/417 reads (23%) | called by muse, mutect2
- BPIFB6 | c.552G>A p.V184= | Silent (SNP) | VAF 246/726 reads (34%) | catalogued as COSV62755480, COSV62755973; called by muse, mutect2, varscan2
- BRAF | c.1920G>A p.V640= (on ENST00000288602 / NM_001374244.1; = p.V600= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 163/322 reads (51%) | catalogued as COSV56107175, COSV56109586; called by muse, mutect2, varscan2
- CA3 | c.60C>T p.F20= | Silent (SNP) | VAF 94/346 reads (27%) | catalogued as COSV53409971; called by muse, mutect2, varscan2
- CCDC77 | c.1371C>T p.V457= | Silent (SNP) | VAF 224/224 reads (100%) | called by muse, mutect2, varscan2
- CCT6A | c.1092G>A p.E364= | Silent (SNP) | VAF 173/535 reads (32%) | called by muse, mutect2, varscan2
- CD1E | c.603G>A p.G201= | Silent (SNP) | VAF 146/334 reads (44%) | catalogued as rs1182262181; called by muse, mutect2, varscan2
- CHPF2 | c.1461C>T p.T487= | Silent (SNP) | VAF 256/851 reads (30%) | called by muse, mutect2, varscan2
- CNR2 | c.456G>A p.V152= | Silent (SNP) | VAF 446/818 reads (55%) | called by muse, mutect2
- CNTNAP2 | c.1059G>A p.R353= | Silent (SNP) | VAF 150/495 reads (30%) | catalogued as COSV62255525; called by muse, mutect2, varscan2
- COL15A1 | c.1779G>A p.E593= | Silent (SNP) | VAF 103/398 reads (26%) | called by muse, mutect2, varscan2
- COL4A4 | c.2340G>A p.G780= | Silent (SNP) | VAF 85/284 reads (30%) | catalogued as rs763135916, COSV61632859; called by muse, mutect2, varscan2
- CPXM2 | c.1905G>A p.V635= | Silent (SNP) | VAF 186/202 reads (92%) | catalogued as rs1235991036, COSV99581168; called by muse, mutect2, varscan2
- DNAH5 | c.6003C>T p.V2001= | Silent (SNP) | VAF 103/557 reads (18%) | catalogued as rs372754085; called by muse, mutect2, varscan2
- DNAJC30 | c.117C>T p.S39= | Silent (SNP) | VAF 631/979 reads (64%) | catalogued as rs1554611810; called by muse, mutect2, varscan2
- DNAJC5B | c.84G>A p.K28= | Silent (SNP) | VAF 81/329 reads (25%) | called by muse, mutect2, varscan2
- DTNB | c.1635C>T p.P545= | Silent (SNP) | VAF 219/667 reads (33%) | called by muse, mutect2, varscan2
- DYSF | c.4395C>T p.P1465= | Silent (SNP) | VAF 107/357 reads (30%) | called by muse, mutect2, varscan2
- EML6 | c.1983C>T p.N661= | Silent (SNP) | VAF 75/306 reads (25%) | called by muse, mutect2, varscan2
- ENPP6 | c.618G>A p.R206= | Silent (SNP) | VAF 383/383 reads (100%) | catalogued as COSV57067066; called by muse, mutect2, varscan2
- ENTPD2 | c.930C>T p.C310= | Silent (SNP) | VAF 554/554 reads (100%) | called by muse, mutect2, varscan2
- FAM184A | c.1318C>T p.L440= | Silent (SNP) | VAF 133/133 reads (100%) | catalogued as rs961351492, COSV100137786; called by muse, mutect2, varscan2
- FLNB | c.6609G>A p.L2203= | Silent (SNP) | VAF 361/363 reads (99%) | called by muse, mutect2, varscan2
- FLNC | c.1722C>T p.V574= | Silent (SNP) | VAF 544/863 reads (63%) | called by muse, mutect2, varscan2
- GABRG2 | c.1152C>T p.I384= (on ENST00000361925 / NM_001375343.1; = p.I344= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/425 reads (21%) | catalogued as COSV62719100; called by muse, mutect2, varscan2
- GNG14 | c.276G>A p.P92= | Silent (SNP) | VAF 22/386 reads (6%) | catalogued as rs1279682021; called by muse, mutect2
- GOT2 | c.942C>T p.P314= | Silent (SNP) | VAF 111/402 reads (28%) | catalogued as COSV99803809; called by muse, mutect2, varscan2
- GRM8 | c.1884G>A p.G628= | Silent (SNP) | VAF 469/712 reads (66%) | catalogued as COSV58841588; called by muse, mutect2, varscan2
- GRXCR1 | c.60C>T p.I20= | Silent (SNP) | VAF 242/678 reads (36%) | catalogued as rs267600162, COSV67669835; called by muse, mutect2, varscan2
- GUCY2C | c.84G>A p.Q28= | Silent (SNP) | VAF 405/405 reads (100%) | catalogued as COSV99663588; called by muse, mutect2, varscan2
- H2BC4 | c.15C>A p.A5= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV58416792; called by muse, mutect2, varscan2
- HCAR1 | c.663C>T p.F221= | Silent (SNP) | VAF 413/572 reads (72%) | called by muse, mutect2, varscan2
- HTR6 | c.790C>T p.L264= | Silent (SNP) | VAF 513/937 reads (55%) | called by muse, mutect2, varscan2
- HYDIN | c.13590C>T p.D4530= | Silent (SNP) | VAF 253/418 reads (61%) | called by muse, mutect2, varscan2
- IBA57 | c.297C>T p.F99= | Silent (SNP) | VAF 365/775 reads (47%) | catalogued as COSV64510799; called by muse, mutect2, varscan2
- IDH3G | c.1134C>T p.D378= | Silent (SNP) | VAF 140/578 reads (24%) | catalogued as rs781912650, COSV54208180; called by muse, varscan2
- IQCG | c.243C>T p.I81= | Silent (SNP) | VAF 103/404 reads (25%) | catalogued as COSV54561366; called by muse, mutect2, varscan2
- ITGAV | c.426C>T p.Y142= | Silent (SNP) | VAF 76/216 reads (35%) | called by muse, mutect2, varscan2
- KCNG1 | c.882C>T p.F294= | Silent (SNP) | VAF 467/1113 reads (42%) | catalogued as rs141429244; called by muse, mutect2, varscan2
- KIF6 | c.516G>T p.V172= | Silent (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- LRP1B | c.6093G>A p.K2031= | Silent (SNP) | VAF 86/259 reads (33%) | catalogued as rs752370092, COSV67197428, COSV67209627; called by muse, mutect2, varscan2
- LTBP2 | c.1770C>T p.A590= | Silent (SNP) | VAF 169/763 reads (22%) | called by muse, mutect2, varscan2
- LTK | c.216C>T p.T72= | Silent (SNP) | VAF 437/749 reads (58%) | called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.168C>A p.G56= | Silent (SNP) | VAF 311/891 reads (35%) | catalogued as COSV65443173; called by muse, mutect2, varscan2
- MDGA1 | c.2505C>T p.S835= | Silent (SNP) | VAF 114/368 reads (31%) | called by muse, mutect2, varscan2
- MEF2D | c.1224C>T p.V408= | Silent (SNP) | VAF 272/590 reads (46%) | called by muse, mutect2, varscan2
- MRPS18A | c.198C>T p.P66= | Silent (SNP) | VAF 60/277 reads (22%) | called by muse, mutect2, varscan2
- MSANTD3-TMEFF1 | c.75C>T p.A25= | Silent (SNP) | VAF 10/290 reads (3%) | called by muse, mutect2
- MUC16 | c.25872T>C p.A8624= | Silent (SNP) | VAF 472/489 reads (97%) | called by muse, mutect2, varscan2
- MUC5B | c.9219C>T p.T3073= | Silent (SNP) | VAF 212/686 reads (31%) | catalogued as rs370975937; called by muse, mutect2, varscan2
- MVD | c.183C>T p.T61= | Silent (SNP) | VAF 200/335 reads (60%) | catalogued as rs568814170, COSV56329663, COSV56331945; called by muse, mutect2, varscan2
- MYLK | c.2883G>A p.G961= | Silent (SNP) | VAF 119/480 reads (25%) | catalogued as rs1476749885; called by muse, mutect2, varscan2
- MYO16 | c.3261C>T p.F1087= | Silent (SNP) | VAF 152/152 reads (100%) | catalogued as rs1157856257, COSV62752930; called by muse, mutect2, varscan2
- MYO18B | c.4380G>A p.L1460= | Silent (SNP) | VAF 447/448 reads (100%) | called by muse, varscan2
- MYO18B | c.4624A>C p.R1542= | Silent (SNP) | VAF 26/612 reads (4%) | called by muse, mutect2
- MYOM3 | c.819C>T p.F273= | Silent (SNP) | VAF 286/494 reads (58%) | catalogued as COSV58398276; called by muse, varscan2
- NPC1L1 | c.1023C>T p.F341= | Silent (SNP) | VAF 345/1056 reads (33%) | catalogued as COSV56924195; called by muse, mutect2, varscan2
- NXPH3 | c.444C>T p.L148= | Silent (SNP) | VAF 38/864 reads (4%) | catalogued as rs1300573999; called by muse, mutect2
- OLFML3 | c.1137C>T p.P379= | Silent (SNP) | VAF 265/289 reads (92%) | called by muse, mutect2, varscan2
- OR10J3 | c.429C>T p.I143= | Silent (SNP) | VAF 240/538 reads (45%) | catalogued as COSV59954289; called by muse, mutect2, varscan2
- OR10K2 | c.115C>T p.L39= | Silent (SNP) | VAF 208/449 reads (46%) | catalogued as COSV100149373; called by muse, mutect2, varscan2
- OR11L1 | c.819C>T p.I273= | Silent (SNP) | VAF 153/289 reads (53%) | catalogued as COSV100869410, COSV63313737; called by muse, mutect2, varscan2
- OR3A2 | c.366C>T p.F122= | Silent (SNP) | VAF 474/574 reads (83%) | catalogued as COSV101375048; called by muse, mutect2, varscan2
- OR4N2 | c.210T>C p.D70= | Silent (SNP) | VAF 78/862 reads (9%) | called by muse, mutect2
- OR52H1 | c.126G>A p.V42= (on ENST00000322653; = p.V48= on NM_001005289.1) | Silent (SNP) | VAF 17/365 reads (5%) | catalogued as COSV100497244; called by muse, mutect2
- OTUD7B | c.1341T>A p.P447= | Silent (SNP) | VAF 197/433 reads (45%) | called by muse, mutect2, varscan2
- P3H3 | c.1128C>T p.I376= | Silent (SNP) | VAF 261/261 reads (100%) | called by muse, mutect2, varscan2
- PELP1 | c.3291C>T p.L1097= | Silent (SNP) | VAF 261/322 reads (81%) | catalogued as rs535963672; called by muse, varscan2
- PITPNC1 | c.600G>C p.V200= | Silent (SNP) | VAF 348/348 reads (100%) | called by muse, mutect2, varscan2
- PKD2L1 | c.411C>T p.F137= | Silent (SNP) | VAF 182/182 reads (100%) | catalogued as rs751818688; called by muse, mutect2, varscan2
- PLEKHH3 | c.1575G>A p.R525= | Silent (SNP) | VAF 625/627 reads (100%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.1362T>C p.C454= | Silent (SNP) | VAF 65/602 reads (11%) | called by muse, mutect2, varscan2
- PREX2 | c.4620G>A p.V1540= | Silent (SNP) | VAF 310/443 reads (70%) | catalogued as rs1392322667; called by muse, mutect2, varscan2
- PRKDC | c.6966T>C p.V2322= | Silent (SNP) | VAF 13/323 reads (4%) | called by muse, mutect2
- PWWP2B | c.1446G>A p.T482= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as rs747970527; called by muse, mutect2
- PXMP2 | c.72G>A p.Q24= | Silent (SNP) | VAF 500/703 reads (71%) | catalogued as rs1300262385; called by muse, mutect2, varscan2
- PYROXD1 | c.585A>C p.S195= | Silent (SNP) | VAF 13/363 reads (4%) | catalogued as COSV53709169; called by muse, mutect2
- RBM24 | c.399C>T p.V133= (on ENST00000379052 / NM_001143942.2; = p.V88= on NM_153020.2) | Silent (SNP) | VAF 86/301 reads (29%) | called by muse, mutect2, varscan2
- RBM27 | c.525C>T p.G175= | Silent (SNP) | VAF 89/457 reads (19%) | called by muse, mutect2, varscan2
- RBM27 | c.526C>T p.L176= | Silent (SNP) | VAF 88/454 reads (19%) | called by muse, mutect2, varscan2
- RBX1 | c.63C>A p.R21= | Silent (SNP) | VAF 48/870 reads (6%) | called by muse, mutect2
- RELN | c.7839C>T p.F2613= | Silent (SNP) | VAF 277/463 reads (60%) | catalogued as COSV104414858; called by muse, mutect2, varscan2
- RIMBP3 | c.4074A>G p.Q1358= | Silent (SNP) | VAF 445/1042 reads (43%) | called by muse, varscan2
- RNF152 | c.483G>A p.V161= | Silent (SNP) | VAF 325/325 reads (100%) | called by muse, mutect2, varscan2
- RPL39 | c.36C>T p.F12= | Silent (SNP) | VAF 251/253 reads (99%) | catalogued as COSV64294152; called by muse, mutect2, varscan2
- SCNN1B | c.1137G>A p.T379= | Silent (SNP) | VAF 93/343 reads (27%) | catalogued as rs751969143, COSV100225734; called by muse, mutect2, varscan2
- SENP6 | c.2187T>G p.T729= | Silent (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.105C>T p.H35= | Silent (SNP) | VAF 408/408 reads (100%) | catalogued as rs1421048502, COSV100820486; called by muse, varscan2
- SEZ6L2 | c.2394C>T p.F798= (on ENST00000308713 / NM_001114099.3; = p.F728= on NM_012410.4) | Silent (SNP) | VAF 212/423 reads (50%) | called by muse, mutect2, varscan2
- SH3GLB2 | c.132C>T p.A44= | Silent (SNP) | VAF 471/471 reads (100%) | catalogued as rs762119648; called by muse, mutect2, varscan2
- SLC22A16 | c.57C>T p.F19= | Silent (SNP) | VAF 103/103 reads (100%) | called by muse, mutect2, varscan2
- SLC36A1 | c.912C>T p.I304= | Silent (SNP) | VAF 124/533 reads (23%) | called by muse, mutect2, varscan2
- SPEN | c.4602A>T p.S1534= | Silent (SNP) | VAF 99/632 reads (16%) | called by muse, mutect2, varscan2
- SYNE1 | c.6138C>T p.A2046= (on ENST00000367255 / NM_182961.4; = p.A2053= on NM_033071.3) | Silent (SNP) | VAF 234/234 reads (100%) | called by muse, mutect2, varscan2
- THNSL2 | c.1323C>T p.I441= | Silent (SNP) | VAF 277/422 reads (66%) | catalogued as rs769151866, COSV59083211; called by muse, mutect2, varscan2
- TMEM108 | c.153G>C p.V51= | Silent (SNP) | VAF 166/581 reads (29%) | called by muse, mutect2, varscan2
- TP53 | c.1023C>T p.F341= | Silent (SNP) | VAF 578/578 reads (100%) | catalogued as rs864622369, COSV52693704, COSV52845855, COSV99411018; ClinVar: likely benign; called by muse, mutect2, varscan2
- VAC14 | c.2343C>T p.V781= | Silent (SNP) | VAF 177/309 reads (57%) | called by muse, mutect2, varscan2
- VEPH1 | c.738G>A p.K246= | Silent (SNP) | VAF 156/269 reads (58%) | called by muse, mutect2, varscan2
- VPS13A | c.7725G>A p.E2575= | Silent (SNP) | VAF 297/298 reads (100%) | called by muse, mutect2, varscan2
- VSIG1 | c.714G>A p.G238= | Silent (SNP) | VAF 319/319 reads (100%) | called by muse, mutect2, varscan2
- VWA5B1 | c.1881C>T p.P627= | Silent (SNP) | VAF 285/520 reads (55%) | catalogued as rs1230084243; called by muse, varscan2
- ZNF479 | c.1302G>A p.E434= | Silent (SNP) | VAF 101/459 reads (22%) | called by muse, mutect2, varscan2
- ZNF544 | c.1683T>C p.S561= | Silent (SNP) | VAF 286/310 reads (92%) | called by muse, mutect2, varscan2
- ZNF618 | c.1476C>T p.F492= (on ENST00000374126 / NM_001318042.2; = p.F399= on NM_133374.2) | Silent (SNP) | VAF 518/518 reads (100%) | catalogued as COSV99930993; called by muse, mutect2, varscan2
- ZNF638 | c.1140C>T p.P380= | Silent (SNP) | VAF 200/320 reads (63%) | catalogued as COSV100040033; called by muse, mutect2, varscan2
- ZNF736 | c.936C>A p.P312= | Silent (SNP) | VAF 84/664 reads (13%) | catalogued as COSV100755721; called by mutect2, varscan2
- ACACA | c.338+1276C>T | Intron (SNP) | VAF 403/403 reads (100%) | called by muse, mutect2, varscan2
- AL132655.6 | n.36G>A | RNA (SNP) | VAF 355/796 reads (45%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.835-324T>G | Intron (SNP) | VAF 66/846 reads (8%) | called by muse, mutect2
- CNTN2 | c.*494C>T | 3'UTR (SNP) | VAF 279/585 reads (48%) | catalogued as rs892082740; called by muse, varscan2
- DLX4 | c.284-57C>T | Intron (SNP) | VAF 547/547 reads (100%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2738-4558G>A | Intron (SNP) | VAF 167/224 reads (75%) | called by muse, mutect2, varscan2
- GFRA1 | c.*2305T>G | 3'UTR (SNP) | VAF 191/397 reads (48%) | called by muse, mutect2, varscan2
- KRBA1 | c.-42C>T | 5'UTR (SNP) | VAF 157/692 reads (23%) | catalogued as rs746568125; called by muse, mutect2, varscan2
- LDAH | c.*1997C>T | 3'UTR (SNP) | VAF 47/216 reads (22%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+7500G>C | Intron (SNP) | VAF 245/892 reads (27%) | called by muse, mutect2, varscan2
- MBD1 | c.793-172C>G | Intron (SNP) | VAF 10/403 reads (2%) | called by muse, mutect2
- MUCL3 | c.947-720A>T | Intron (SNP) | VAF 414/704 reads (59%) | called by mutect2, varscan2
- NBPF25P | n.2025C>T | RNA (SNP) | VAF 158/528 reads (30%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49595433 G>A | 5'Flank (SNP) | VAF 399/425 reads (94%) | catalogued as rs1250460604; called by muse, mutect2, varscan2
- PRR12 | chr19:49595434 G>A | 5'Flank (SNP) | VAF 394/419 reads (94%) | catalogued as rs984401980; called by muse, mutect2, varscan2
- TP53TG3D | c.*193C>T | 3'UTR (SNP) | VAF 193/316 reads (61%) | catalogued as rs1417441446; called by muse, mutect2, varscan2
- VSTM2A | c.634+3847C>T | Intron (SNP) | VAF 415/665 reads (62%) | called by muse, mutect2, varscan2
